Somatic mutation profile of tumor specimen TCGA-97-7937-01A (aliquot TCGA-97-7937-01A-11D-2167-08) from TCGA case TCGA-97-7937, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Invasive micropapillary carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.5 years (23,919 days).
Specimen TCGA-97-7937-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21b53a70-5a74-49b3-bf88-957cded57e82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7937-10A (Blood Derived Normal), aliquot TCGA-97-7937-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1e449cd-167f-41bf-9a90-f1426c88e1da

The open-access MAF lists 484 somatic variants for this specimen: 389 protein-altering or splice-affecting, 90 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 328, Silent 90, Nonsense Mutation 31, Frame Shift Del 18, Splice Site 8, Splice Region 3, Intron 2, RNA 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM002273, COSV55670863; called by muse, mutect2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.241T>A p.W81R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52629636; called by muse, mutect2, varscan2
- ABCA13 | c.8398G>A p.D2800N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1308301425, COSV71291645; called by muse, mutect2, varscan2
- ABCG5 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as rs1369776473, COSV53212115; called by muse, mutect2, varscan2
- ACTN2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV63976970; called by muse, mutect2, varscan2
- ADAMTS13 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63022337; called by muse, mutect2, varscan2
- ADAMTS7 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.19); catalogued as COSV101183029; called by muse, mutect2, varscan2
- ADAMTSL1 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52813631, COSV52816035, COSV52820375; called by muse, mutect2, varscan2
- ADGRF4 | c.1429A>C p.T477P | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51955168; called by muse, mutect2, varscan2
- ADGRG7 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56299196; called by muse, mutect2, varscan2
- AGL | c.2680T>G p.S894A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV54055890; called by muse, mutect2, varscan2
- AKR1B15 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71151188; called by muse, mutect2, varscan2
- ALPK2 | c.2311C>A p.P771T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1366070969, COSV64494929; called by muse, mutect2, varscan2
- AMER3 | c.1696C>A p.Q566K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58468478, COSV58468700; called by muse, mutect2
- AMPD2 | c.209A>T p.K70M | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56649332; called by muse, mutect2, varscan2
- ANK2 | c.10150C>G p.P3384A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV52175748; called by muse, mutect2, varscan2
- ANKFY1 | c.3205C>T p.R1069C (on ENST00000341657 / NM_001330063.2; = p.R1070C on NM_016376.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs947729298, COSV58920052; called by muse, mutect2, varscan2
- ANKRD16 | c.338C>G p.T113R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758268673, COSV51948281; called by muse, mutect2, varscan2
- ANKRD42 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52617199; called by muse, mutect2, varscan2
- AP2A2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59962495; called by muse, mutect2, varscan2
- APOOL | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as COSV64272260; called by muse, mutect2, varscan2
- ARFGEF3 | c.5345G>T p.R1782M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV52464190; called by muse, mutect2, varscan2
- ARHGAP21 | c.3340A>G p.T1114A | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); catalogued as COSV57609045; called by muse, mutect2, varscan2
- ARL4D | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60721711; called by muse, mutect2, varscan2
- ASTN2 | c.1763G>T p.S588I (on ENST00000313400 / NM_001365069.1; = p.S537I on NM_014010.5) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1255371250, COSV57799363; called by muse, mutect2, varscan2
- ATAD2 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV54884237; called by mutect2, varscan2
- ATCAY | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV56657751; called by muse, mutect2, varscan2
- ATP1A2 | c.155A>T p.K52I | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63404950; called by muse, mutect2, varscan2
- ATP2B3 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV54855202; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59478209; called by muse, mutect2, varscan2
- ATP6V0B | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52544285; called by muse, mutect2, varscan2
- BCL11A | c.2302T>C p.C768R (on ENST00000335712 / NM_001365609.1; = p.C802R on NM_022893.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59633954; called by muse, mutect2, varscan2
- BDH1 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV64019189; called by muse, mutect2, varscan2
- BMP7 | c.1175C>G p.P392R | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101216214, COSV67781678; called by muse, mutect2, varscan2
- BMS1 | c.40A>T p.S14C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65734775, COSV65735025; called by muse, mutect2, varscan2
- BRD8 | c.2492G>A p.R831Q (on ENST00000254900 / NM_139199.2; = p.R904Q on NM_006696.4) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50154907; called by muse, mutect2, varscan2
- BRDT | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV62866266; called by muse, mutect2, varscan2
- BRINP3 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV66532858; called by muse, mutect2, varscan2
- BST2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV53089388; called by muse, mutect2, varscan2
- C12orf66 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100320587; called by muse, mutect2, varscan2
- C5AR1 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV61892319, COSV61893009; called by muse, mutect2, varscan2
- C7 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.697); catalogued as COSV57477523; called by muse, mutect2, varscan2
- CACNA1C | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59747860; called by muse, mutect2, varscan2
- CACNA1C | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59747910, COSV59785774; called by muse, mutect2, varscan2
- CADPS | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51892283, COSV99337318; called by muse, mutect2, varscan2
- CALB1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); catalogued as rs1299660601, COSV55368606; called by muse, mutect2, varscan2
- CALN1 | c.328G>T p.G110C (on ENST00000329008 / NM_001017440.3; = p.G152C on NM_031468.4) | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV61133883, COSV61142647; called by muse, mutect2, varscan2
- CAMK2N1 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100906989; called by muse, mutect2, varscan2
- CAMK4 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV56677647; called by muse, mutect2, varscan2
- CARD19 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.363); catalogued as COSV64936076; called by muse, mutect2, varscan2
- CASP14 | c.521-1G>T p.X174_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as COSV55666024, COSV99693112; called by muse, mutect2
- CASP2 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100130899; called by muse, mutect2, varscan2
- CBL | c.1202G>T p.C401F | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50629831, COSV50631474, COSV50648655; called by muse, mutect2, varscan2
- CBLIF | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV57239787; called by muse, mutect2, varscan2
- CCDC127 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 96/150 reads (64%) | catalogued as COSV57256170, COSV57257622; called by muse, mutect2, varscan2
- CCDC178 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as rs1265879484, COSV55785739; called by mutect2, varscan2
- CCDC180 | c.1840A>T p.K614* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63832889; called by muse, mutect2, varscan2
- CCDC40 | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV66476748; called by muse, mutect2, varscan2
- CCKBR | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475288494, COSV58103607; called by muse, mutect2, varscan2
- CD163 | c.2403C>A p.H801Q | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.576); catalogued as COSV63131083, COSV63135337; called by muse, mutect2, varscan2
- CDH18 | c.1436T>C p.L479P | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56943031; called by muse, mutect2, varscan2
- CDH2 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99295956; called by mutect2, varscan2
- CDH2 | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV99295963; called by muse, mutect2, varscan2
- CDH3 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.768); catalogued as COSV50563425; called by muse, mutect2, varscan2
- CDS1 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55689388; called by muse, mutect2, varscan2
- CDYL | c.135C>A p.S45R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61043447; called by muse, mutect2, varscan2
- CFAP69 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV60187080; called by muse, mutect2, varscan2
- CFH | c.1260C>A p.Y420* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100661424, COSV62778324; called by muse, mutect2, varscan2
- CFHR1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as rs1333832830, COSV57628203; called by muse, mutect2, varscan2
- CHRNB3 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51495078, COSV51495562; called by muse, mutect2, varscan2
- CLIP2 | c.2840A>C p.K947T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV56282698; called by muse, mutect2, varscan2
- CLPTM1L | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.863); catalogued as COSV57991698; called by muse, mutect2, varscan2
- COBL | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.095); catalogued as COSV54352056; called by muse, mutect2, varscan2
- COL11A1 | c.3601-1G>T p.X1201_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100615406; called by muse, mutect2, varscan2
- COL11A1 | c.2698C>A p.P900T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV62190247; called by muse, mutect2, varscan2
- COL14A1 | c.5296G>C p.A1766P | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV52861972; called by muse, mutect2, varscan2
- COL25A1 | c.1675G>T p.G559* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV67654540; called by muse, mutect2, varscan2
- COL4A2 | c.892A>T p.M298L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64631209; called by muse, mutect2, varscan2
- COL6A6 | c.880C>A p.Q294K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV62031799; called by muse, mutect2, varscan2
- COPS4 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs751003224, COSV52315659; called by muse, mutect2, varscan2
- CORO1C | c.150A>G p.I50M | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV54597774; called by muse, mutect2, varscan2
- CR1L | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV54329068; called by muse, mutect2, varscan2
- CTCF | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV50489849, COSV99864074; called by muse, mutect2, varscan2
- CTNNA2 | c.2746C>A p.L916I (on ENST00000402739 / NM_001282597.3; = p.L868I on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1011109638, COSV100559590; called by muse, mutect2, varscan2
- CUBN | c.6820A>T p.N2274Y | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64722110; called by muse, mutect2, varscan2
- CUX2 | c.2884C>A p.Q962K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV55640660; called by muse, mutect2, varscan2
- CUZD1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100158630, COSV100158748; called by muse, mutect2, varscan2
- CXorf66 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV65169564; called by muse, mutect2, varscan2
- CYP11B1 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs748062304, COSV52829032, COSV99454309; called by muse, mutect2, varscan2
- DCAF5 | c.2572G>C p.A858P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.093); catalogued as COSV58461744; called by muse, mutect2, varscan2
- DCP1A | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.844); catalogued as COSV53689636; called by muse, mutect2, varscan2
- DENND6B | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs369679219, COSV101306036; called by muse, mutect2, varscan2
- DGAT2L6 | c.579C>A p.C193* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV60718284; called by muse, mutect2, varscan2
- DMD | c.3738C>G p.N1246K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV63776047; called by muse, mutect2, varscan2
- DNAH11 | c.11561G>C p.W3854S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60967998; called by muse, mutect2
- DNAH2 | c.1821C>A p.D607E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV50017608; called by muse, mutect2, varscan2
- DNAH2 | c.10111G>T p.G3371W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049322174, COSV66722971; called by muse, mutect2, varscan2
- DOCK10 | c.1930A>G p.M644V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51421829; called by muse, mutect2, varscan2
- DPPA3 | c.246G>T p.R82S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV61503315; called by muse, mutect2, varscan2
- DPYS | c.424-1G>T p.X142_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV60911338; called by muse, mutect2, varscan2
- EEA1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59288169; called by muse, mutect2, varscan2
- ELL | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53211584, COSV53214390; called by muse, varscan2
- EMILIN2 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54425645; called by muse, mutect2, varscan2
- EPHA6 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101061108, COSV67579144; called by muse, mutect2, varscan2
- EPHA6 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101061112, COSV67572340; called by muse, mutect2, varscan2
- ERCC6L2 | c.786C>T p.N262= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as rs540770553, COSV56632683; called by muse, mutect2, varscan2
- ETNPPL | c.1407C>A p.D469E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV56596759; called by muse, mutect2, varscan2
- EXT1 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65482525; called by muse, mutect2, varscan2
- F7 | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747989049, CM051920, CM073037, COSV60646194, COSV60647098; called by muse, varscan2
- FAM126B | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750157160, COSV53772950, COSV53773989; called by muse, mutect2, varscan2
- FAM171A1 | c.2561G>T p.R854I | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV65317891; called by muse, mutect2, varscan2
- FAM214B | c.1172T>G p.V391G | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59716997; called by muse, mutect2, varscan2
- FAP | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV51864884; called by muse, mutect2, varscan2
- FBLN1 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53045658, COSV53051007, COSV99410689; called by muse, mutect2
- FHDC1 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs780972369, COSV52601690; called by muse, mutect2, varscan2
- FLG | c.2824C>A p.Q942K | Missense Mutation (SNP) | VAF 99/547 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV64245090; called by muse, mutect2, varscan2
- FSTL5 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60212886; called by muse, mutect2, varscan2
- FTSJ1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50026154; called by muse, mutect2, varscan2
- GALNT17 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV61153886, COSV61176768; called by muse, mutect2, varscan2
- GALP | c.87+2T>C p.X29_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV62000681; called by muse, mutect2
- GIGYF2 | c.1920G>T p.L640F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as COSV65251762; called by muse, mutect2, varscan2
- GIMAP6 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | catalogued as COSV61034180; called by muse, mutect2, varscan2
- GPR39 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV61425909; called by muse, mutect2
- GPR61 | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV63984212; called by muse, mutect2, varscan2
- GPRIN2 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555801030, COSV65401767; called by muse, mutect2
- GRIN2A | c.3315C>A p.Y1105* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as COSV58046681; called by muse, mutect2, varscan2
- GRM8 | c.2072G>T p.S691I | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100281213, COSV58861474; called by muse, mutect2, varscan2
- GRM8 | c.2071A>T p.S691C | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100281215; called by muse, mutect2, varscan2
- GSG1L | c.836A>T p.E279V (on ENST00000447459 / NM_001109763.2; = p.E124V on NM_144675.2) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.699); catalogued as COSV66580554; called by muse, mutect2, varscan2
- GTF3C5 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100565270; called by muse, mutect2
- H2BC8 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV55127398; called by muse, mutect2, varscan2
- HBD | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53083191; called by muse, mutect2, varscan2
- HEPACAM2 | c.1378C>A p.H460N (on ENST00000394468 / NM_001039372.4; = p.H448N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV59062106; called by muse, mutect2, varscan2
- HEY2 | c.361T>C p.F121L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV64240366; called by muse, mutect2, varscan2
- IFI27L1 | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.018); catalogued as COSV67628825; called by muse, mutect2, varscan2
- IFNL2 | c.148T>A p.S50T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV59593842; called by muse, mutect2, varscan2
- IGDCC3 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV60076396, COSV60078795; called by muse, mutect2, varscan2
- IGFN1 | c.3470C>A p.P1157H (on ENST00000295591 / NM_001367841.1; = p.P3614H on NM_001164586.2) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55171482, COSV55178976; called by muse, mutect2, varscan2
- IMMP2L | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs374545050; called by muse, mutect2, varscan2
- INSRR | c.3371C>A p.S1124Y | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63875065, COSV63875596; called by muse, mutect2, varscan2
- INSRR | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV63875612; called by muse, mutect2, varscan2
- IRGQ | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60671113; called by muse, mutect2, varscan2
- ISOC1 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.992); catalogued as rs772441077, COSV51492391; called by muse, mutect2, varscan2
- ISX | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58087705; called by muse, mutect2, varscan2
- ITGA7 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV57698163; called by muse, mutect2, varscan2
- ITGAX | c.2393A>T p.N798I | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as COSV51648784; called by muse, mutect2, varscan2
- ITIH5 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.919); catalogued as COSV56909991; called by muse, mutect2, varscan2
- JPH3 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52471350; called by muse, mutect2, varscan2
- KCNA10 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.121); catalogued as COSV63905033; called by muse, mutect2, varscan2
- KCND3 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56185427; called by muse, mutect2, varscan2
- KCNJ3 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV54540434; called by muse, mutect2, varscan2
- KCNK9 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs996007406, COSV57285543; called by muse, mutect2, varscan2
- KCNU1 | c.3223C>G p.P1075A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67756712; called by muse, mutect2, varscan2
- KCTD7 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51877170; called by muse, mutect2, varscan2
- KDM5D | c.1508G>T p.W503L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58736855; called by muse, mutect2, varscan2
- KIF19 | c.1438C>G p.R480G | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV63430083; called by muse, mutect2, varscan2
- KIF21B | c.4895G>A p.R1632H (on ENST00000422435 / NM_001252100.2; = p.R1619H on NM_017596.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs757337335, COSV59752797; called by muse, varscan2
- KLHL30 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100014065, COSV59975399, COSV59977403; called by muse, mutect2, varscan2
- KLHL4 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV64145407; called by muse, mutect2, varscan2
- KPNA2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV57858360; called by muse, mutect2, varscan2
- LCE1C | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64218615; called by muse, mutect2, varscan2
- LCN1 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as rs1330163557, COSV55018830; called by muse, mutect2, varscan2
- LCT | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1364789897, COSV51550664, COSV51553974; called by muse, mutect2, varscan2
- LDHC | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV55005188; called by muse, mutect2, varscan2
- LEP | c.326A>T p.H109L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV58241399; called by muse, mutect2, varscan2
- LINGO2 | c.1519C>A p.R507S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV58058037, COSV58061817; called by muse, mutect2, varscan2
- LINS1 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59080127; called by muse, mutect2, varscan2
- LLGL2 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV51376634; called by muse, mutect2, varscan2
- LMO3 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53782258; called by muse, mutect2, varscan2
- LRP1B | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67215294, COSV67251085; called by muse, mutect2
- LRP1B | c.1072G>C p.G358R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67251089; called by muse, mutect2, varscan2
- LRRCC1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV64484518; called by muse, mutect2, varscan2
- LYRM7 | c.19del p.X7_splice | Splice Site (DEL) | VAF 28/59 reads (47%) | catalogued as COSV65086094; called by mutect2, pindel, varscan2
- MAG | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62701912; called by muse, mutect2, varscan2
- MAN1B1 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.211); catalogued as COSV63035016; called by muse, mutect2, varscan2
- MARCHF11 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV60128655, COSV60131962; called by muse, mutect2, varscan2
- MBL2 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 192/328 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV64758989, COSV64759043; called by muse, varscan2
- MCEMP1 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs267605762, COSV58040506; called by muse, mutect2, varscan2
- MEOX2 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100012482, COSV56292661; called by muse, mutect2, varscan2
- MERTK | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99774183; called by muse, mutect2, varscan2
- MFSD2A | c.913G>T p.G305C (on ENST00000372809 / NM_001136493.3; = p.G292C on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65686178, COSV65686487; called by muse, mutect2, varscan2
- MMS22L | c.237G>C p.W79C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51523726; called by muse, mutect2, varscan2
- MPO | c.1956G>T p.K652N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51860895; called by muse, mutect2, varscan2
- MRAP2 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.667); catalogued as COSV100004666; called by muse, mutect2, varscan2
- MRC1 | c.3985C>T p.R1329W | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs782546027; called by muse, mutect2, varscan2
- MRGPRX1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV57107399, COSV57108718; called by muse, mutect2, varscan2
- MS4A1 | c.337-1G>T p.X113_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100619405, COSV61941753; called by muse, mutect2, varscan2
- MT1M | c.123T>A p.C41* | Nonsense Mutation (SNP) | VAF 87/158 reads (55%) | catalogued as rs761741726, COSV51947751; called by muse, mutect2, varscan2
- MTMR6 | c.1397A>C p.K466T | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV67809126; called by muse, mutect2, varscan2
- MTNR1B | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 50/127 reads (39%) | catalogued as COSV57067682; called by muse, mutect2, varscan2
- MTRR | c.326C>T p.P109L (on ENST00000264668; = p.P82L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs747303076, CM159483, COSV52945502; called by muse, mutect2, varscan2
- MUC16 | c.39627C>G p.S13209R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.838); catalogued as COSV66691503, COSV66694769; called by muse, mutect2, varscan2
- MUC17 | c.11261T>A p.L3754H | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV60296555; called by muse, mutect2, varscan2
- MUC5AC | c.15554G>C p.C5185S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611338; called by muse, mutect2, varscan2
- MYH2 | c.5133G>C p.E1711D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV55443540; called by muse, mutect2
- MYH4 | c.4813C>A p.L1605M | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55117046, COSV55122765; called by muse, mutect2, varscan2
- MYH7 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1410564846, COSV62521631; called by muse, mutect2, varscan2
- MYH8 | c.3842C>A p.A1281E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV67961717, COSV67969288; called by muse, mutect2, varscan2
- NCAN | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53054863; called by muse, mutect2, varscan2
- NCF2 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV62316207; called by muse, mutect2, varscan2
- NCKAP1 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62942387; called by muse, mutect2, varscan2
- NEB | c.14755G>T p.V4919L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.202); catalogued as COSV51438888; called by muse, mutect2, varscan2
- NELL1 | c.1606G>T p.V536F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs1408294625, COSV54296112; called by muse, mutect2, varscan2
- NEU4 | c.1006C>A p.R336S (on ENST00000391969 / NM_001167602.3; = p.R348S on NM_080741.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57990348; called by muse, mutect2
- NEXMIF | c.3725G>T p.G1242V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV50031970; called by muse, mutect2, varscan2
- NFAT5 | c.2155A>T p.R719* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV63030215; called by muse, mutect2, varscan2
- NIBAN3 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs934921674, COSV56311790; called by muse, mutect2, varscan2
- NLRP5 | c.1505A>G p.H502R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1212989599, COSV66766217; called by muse, mutect2, varscan2
- NPHS1 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs780251670, COSV62289075; called by muse, mutect2
- NPHS1 | c.1152G>T p.M384I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV62289080; called by muse, mutect2, varscan2
- NR4A2 | c.1042A>C p.K348Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59892847; called by muse, mutect2, varscan2
- NRXN2 | c.5078C>T p.P1693L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs776114680, COSV55447377; called by muse, mutect2, varscan2
- NTNG1 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53980527; called by muse, mutect2, varscan2
- NYAP2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56005570, COSV56011602; called by muse, mutect2, varscan2
- OBSCN | c.10536G>T p.M3512I | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV52802192; called by muse, mutect2, varscan2
- ODF1 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 51/130 reads (39%) | catalogued as COSV53433485; called by muse, mutect2, varscan2
- OGFR | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV51700797; called by muse, varscan2
- OIT3 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.564); catalogued as COSV61826787; called by muse, mutect2, varscan2
- OR13F1 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58252163; called by muse, mutect2, varscan2
- OR13G1 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV62944798; called by muse, mutect2, varscan2
- OR2T27 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV61281368; called by muse, mutect2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR52B2 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs143192617, COSV101603927; called by muse, mutect2, varscan2
- OR52W1 | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV60951399; called by muse, mutect2, varscan2
- OR5B12 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56905926; called by muse, mutect2, varscan2
- OR5F1 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53547700; called by muse, mutect2, varscan2
- OR5H15 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100736626, COSV62947631; called by muse, mutect2, varscan2
- OR5L1 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV61734773; called by muse, mutect2, varscan2
- OR6T1 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV58308364; called by muse, mutect2, varscan2
- OR8J1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs759396550, COSV57319198, COSV57319258; called by muse, mutect2, varscan2
- OR8K3 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs779437194, COSV57131240, COSV57132281; called by muse, mutect2, varscan2
- OR8U1 | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100163786; called by muse, mutect2, varscan2
- PADI3 | c.874C>G p.R292G | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100968413, COSV100968613, COSV64934999; called by muse, mutect2, varscan2
- PADI3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs568276808, COSV100968415; called by muse, mutect2, varscan2
- PAK5 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs748547848, COSV62033131; called by muse, mutect2, varscan2
- PAPPA2 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62805061; called by muse, mutect2, varscan2
- PCDH17 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV64976737; called by muse, mutect2, varscan2
- PCDH17 | c.3409del p.E1137Kfs*3 | Frame Shift Del (DEL) | VAF 33/293 reads (11%) | catalogued as COSV64972957; called by mutect2, pindel, varscan2
- PCDHB12 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV53399082; called by muse, mutect2, varscan2
- PCDHGA5 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.11); catalogued as rs368621667, COSV53902013, COSV53992189; called by muse, mutect2, varscan2
- PCNX4 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV100470004; called by muse, mutect2, varscan2
- PDE1A | c.825-1G>T p.X275_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100113267; called by muse, mutect2, varscan2
- PDE1B | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV54494624; called by muse, mutect2, varscan2
- PDGFD | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV56376879; called by muse, mutect2, varscan2
- PFKFB1 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | PolyPhen possibly damaging (0.495); catalogued as COSV66628918, COSV66628933; called by muse, mutect2, varscan2
- PGBD2 | c.762C>A p.C254* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | catalogued as rs1382771538, COSV61400677; called by muse, mutect2
- PHF23 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.112); catalogued as COSV50038065; called by muse, mutect2, varscan2
- PIK3R1 | c.731T>G p.L244* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV57132724, COSV57134879; called by muse, mutect2
- PITPNM3 | c.734G>T p.R245I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV52597886; called by muse, mutect2, varscan2
- PIWIL2 | c.186del p.P63Qfs*26 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as COSV63251827; called by mutect2, pindel
- PKHD1 | c.2639G>T p.R880L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61887285; called by muse, mutect2, varscan2
- PLCB1 | c.1362C>G p.S454R | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62041139, COSV62060303; called by muse, mutect2, varscan2
- PLCB1 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs759604666, COSV62060310; called by muse, mutect2, varscan2
- PLEKHG4B | c.555G>T p.Q185H (on ENST00000283426; = p.Q541H on NM_052909.5) | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV52051526; called by muse, mutect2, varscan2
- PLXNA4 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.139); catalogued as rs761142540, COSV100322880; called by muse, mutect2, varscan2
- POLR2B | c.2979G>T p.K993N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.593); catalogued as COSV58901769, COSV58902432; called by muse, mutect2, varscan2
- POPDC2 | c.869G>C p.C290S | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51742508; called by muse, mutect2, varscan2
- PPP1R3A | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52888002; called by muse, mutect2, varscan2
- PPP3R2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1306296472, COSV62451908; called by muse, mutect2, varscan2
- PRAMEF20 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57081004; called by muse, mutect2, varscan2
- PRLHR | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53305241, COSV99492691; called by muse, mutect2, varscan2
- PRSS36 | c.1006T>G p.W336G | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51638661; called by muse, mutect2
- PSD2 | c.1934C>A p.P645H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51204951; called by muse, varscan2
- PSD2 | c.1966C>A p.Q656K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV51205002; called by muse, varscan2
- PSG6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV51835600; called by muse, mutect2
- PTCD1 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs763289798, COSV52865823; called by muse, mutect2, varscan2
- PTCH1 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59485465; called by muse, mutect2, varscan2
- PTGIR | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775252968, COSV52192829; called by muse, mutect2, varscan2
- PTPRD | c.2745A>T p.E915D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV61966066; called by muse, mutect2, varscan2
- PTPRD | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61966072, COSV61971833; called by muse, mutect2, varscan2
- RAD21 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52061561; called by muse, mutect2, varscan2
- RARA | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as COSV54194764; called by muse, mutect2, varscan2
- RARS1 | c.1551C>G p.I517M | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV51565013; called by muse, mutect2, varscan2
- RASGRP4 | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV53039344; called by muse, mutect2, varscan2
- RELN | c.4279T>A p.C1427S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59020718; called by muse, mutect2, varscan2
- RIT2 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56302942; called by muse, mutect2, varscan2
- RIT2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99949750; called by muse, mutect2, varscan2
- RSPO2 | c.529G>C p.V177L | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.98); catalogued as COSV52650303; called by muse, mutect2
- RXFP1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57046264, COSV57053560; called by muse, mutect2
- RYR2 | c.3467G>A p.W1156* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100768544; called by muse, mutect2, varscan2
- RYR2 | c.3468G>T p.W1156C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63698956; called by muse, mutect2, varscan2
- SCG5 | c.458C>A p.P153Q (on ENST00000300175 / NM_001144757.2; = p.P152Q on NM_003020.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV55707627; called by mutect2, varscan2
- SCGB1D4 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV62204248; called by muse, mutect2
- SCN2B | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV54051409; called by muse, mutect2, varscan2
- SCN8A | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61987494; called by muse, mutect2, varscan2
- SDK1 | c.2709G>T p.Q903H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67380462; called by muse, mutect2, varscan2
- SDR42E1 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.196); catalogued as COSV61094769; called by muse, mutect2, varscan2
- SEL1L3 | c.2549T>G p.L850R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53545892; called by muse, mutect2, varscan2
- SERPINA6 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.618); catalogued as rs747939841, COSV58586396; called by muse, mutect2, varscan2
- SERPINE1 | c.428C>A p.T143K | Missense Mutation (SNP) | VAF 149/473 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.095); catalogued as COSV56170732, COSV99776654; called by muse, mutect2, varscan2
- SH3RF3 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as rs768751419, COSV100513174, COSV58691095; called by muse, mutect2, varscan2
- SHANK1 | c.2154G>A p.M718I | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV53256843, COSV99522250; called by muse, mutect2, varscan2
- SLC12A7 | c.2909C>T p.A970V | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs140477969; called by muse, mutect2, varscan2
- SLC17A4 | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1330059295, COSV64956764; called by muse, mutect2, varscan2
- SLC1A6 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55672287; called by muse, mutect2, varscan2
- SLC22A1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs763609720, COSV61453223; called by muse, mutect2, varscan2
- SLC24A2 | c.1186G>T p.V396L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53870322; called by muse, mutect2, varscan2
- SLC2A14 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs533625592, COSV61587669; called by muse, mutect2, varscan2
- SLC39A3 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV54118132, COSV54118600; called by muse, mutect2, varscan2
- SLC4A1AP | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV58136357; called by muse, mutect2, varscan2
- SLC5A1 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56687589; called by muse, mutect2, varscan2
- SLC6A2 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54920085; called by muse, mutect2, varscan2
- SLC7A3 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53228380; called by muse, mutect2, varscan2
- SLC8A3 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV100776400, COSV63520178; called by muse, mutect2, varscan2
- SLIT2 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.296); catalogued as COSV56584411; called by muse, mutect2, varscan2
- SMAD4 | c.252G>T p.V84= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV61691495; called by muse, mutect2, varscan2
- SMARCAD1 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62775479, COSV62776190; called by muse, mutect2
- SNRPN | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100577952; called by muse, mutect2, varscan2
- SOGA3 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64107349, COSV64107736; called by muse, mutect2, varscan2
- SORCS3 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs750729533, COSV63793638; called by muse, mutect2, varscan2
- SPTBN4 | c.5139G>T p.K1713N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58955176; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | PolyPhen probably damaging (1); catalogued as COSV56572060; called by muse, mutect2, varscan2
- STON2 | c.1351G>T p.D451Y (on ENST00000649389 / NM_001366849.2; = p.D394Y on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV50848934; called by muse, mutect2, varscan2
- SUPT6H | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV58929640; called by muse, mutect2, varscan2
- SVEP1 | c.6186T>A p.N2062K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.739); catalogued as COSV52841783; called by muse, mutect2, varscan2
- SYNDIG1 | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65237613; called by muse, mutect2, varscan2
- SYNE2 | c.18254A>C p.N6085T | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV59960223; called by muse, mutect2, varscan2
- SYNM | c.1346C>A p.P449Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV60372842; called by muse, mutect2, varscan2
- TAF1L | c.3874A>G p.M1292V | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV54265560; called by muse, mutect2, varscan2
- TAS1R2 | c.794A>T p.Q265L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.325); catalogued as COSV64746088; called by muse, mutect2, varscan2
- TBC1D4 | c.3780G>C p.K1260N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV66490511; called by muse, mutect2, varscan2
- TBCE | c.886A>T p.I296F (on ENST00000366601; = p.I359F on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64006837; called by muse, mutect2, varscan2
- TBX20 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68784736; called by muse, varscan2
- TEK | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as rs772637203, COSV66231032; called by muse, mutect2
- TEKT3 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58628718; called by muse, mutect2, varscan2
- TEP1 | c.4437G>T p.E1479D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.681); catalogued as COSV52996403; called by muse, mutect2, varscan2
- TEX11 | c.2154C>A p.C718* (on ENST00000344304; = p.C703* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV60235062; called by muse, mutect2, varscan2
- TFEC | c.288T>A p.D96E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55404043; called by muse, mutect2, varscan2
- TIAM1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV54563729, COSV99734371; called by muse, mutect2, varscan2
- TLN2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs746576084, COSV60892531; called by muse, mutect2, varscan2
- TMC2 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV62652925, COSV62656122; called by muse, mutect2, varscan2
- TMEM132D | c.2045T>A p.L682H | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.961); catalogued as COSV67161435; called by muse, mutect2, varscan2
- TMEM71 | c.620T>C p.L207P (on ENST00000523829 / NM_001382398.1; = p.L188P on NM_144649.3) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV63458397; called by muse, mutect2, varscan2
- TMPRSS11A | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs1238845111, COSV58359941; called by muse, mutect2
- TMPRSS15 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53044352; called by muse, mutect2, varscan2
- TNFRSF25 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV61069111; called by muse, mutect2, varscan2
- TNR | c.3556G>T p.G1186C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54894856, COSV99687872; called by muse, mutect2, varscan2
- TOX | c.583A>G p.M195V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.438); catalogued as COSV63848690; called by muse, mutect2, varscan2
- TPCN2 | c.1920G>A p.A640= | Splice Region (SNP) | VAF 21/91 reads (23%) | catalogued as rs148607240, COSV53729443; called by muse, mutect2, varscan2
- TPPP2 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58795258; called by muse, mutect2
- TRADD | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50758091; called by muse, mutect2, varscan2
- TRIM56 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV60160260; called by muse, mutect2, varscan2
- TRPA1 | c.945A>T p.R315S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51568272; called by muse, mutect2, varscan2
- TSGA10IP | c.1268C>A p.A423E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as COSV101598392; called by muse, mutect2
- TSHZ3 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.532); catalogued as rs762656477, COSV53675488; called by muse, mutect2, varscan2
- TTC36 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV57097360; called by muse, mutect2
- TTC8 | c.1114G>T p.G372C (on ENST00000338104 / NM_001288781.1; = p.G356C on NM_144596.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57628986; called by muse, mutect2, varscan2
- TTLL7 | c.1844G>T p.S615I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV53086965; called by muse, mutect2, varscan2
- TTN | c.4274C>A p.A1425E (on ENST00000591111; = p.A1379E on NM_003319.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | PolyPhen possibly damaging (0.587); catalogued as COSV60207523; called by muse, mutect2, varscan2
- UACA | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as rs980202429, COSV59857865; called by muse, mutect2, varscan2
- UBR5 | c.5659C>T p.R1887* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV55285407; called by muse, mutect2, varscan2
- UGT2A2 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as COSV54147643, COSV99683923; called by muse, mutect2, varscan2
- UGT2B15 | c.736A>T p.T246S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV57735712; called by muse, mutect2, varscan2
- UNC5D | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54765601, COSV99772837; called by muse, mutect2, varscan2
- USP14 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV55282481; called by muse, mutect2, varscan2
- USP2 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.259); catalogued as COSV52731024; called by muse, mutect2, varscan2
- WDR1 | c.1700G>T p.R567I (on ENST00000382452; = p.R427I on NM_005112.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV101221078; called by muse, mutect2, varscan2
- ZEB1 | c.2624C>A p.S875* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV58050058; called by muse, mutect2
- ZMAT5 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV60243723; called by muse, mutect2, varscan2
- ZNF2 | c.374G>T p.R125M (on ENST00000611147 / NM_001291605.2; = p.R112M on NM_021088.4) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.135); catalogued as COSV99728307; called by muse, mutect2, varscan2
- ZNF347 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV61969929; called by muse, mutect2, varscan2
- ZNF479 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 20/63 reads (32%) | catalogued as COSV58641239; called by muse, mutect2, varscan2
- ZNF518B | c.2337G>T p.R779S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100456587; called by muse, mutect2
- ZNF527 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62232762; called by muse, mutect2, varscan2
- ZNF875 | c.1751G>T p.C584F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60989995, COSV60992686; called by muse, mutect2, varscan2
- ZNFX1 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100871009, COSV65577075; called by muse, mutect2, varscan2
- ANKRD45 | c.462_463del p.Q155Dfs*2 | Frame Shift Del (DEL) | VAF 69/240 reads (29%) | called by pindel, varscan2
- BACH1 | c.923del p.P308Lfs*8 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | called by mutect2, pindel, varscan2
- COL22A1 | c.2114del p.G705Efs*110 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- GET4 | c.624_627del p.N208Kfs*44 | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | called by mutect2, pindel, varscan2
- IRS4 | c.1724del p.G575Dfs*36 | Frame Shift Del (DEL) | VAF 101/189 reads (53%) | called by mutect2, pindel, varscan2
- LGALS4 | c.209del p.G70Afs*37 | Frame Shift Del (DEL) | VAF 35/75 reads (47%) | called by mutect2, pindel, varscan2
- LTBP1 | c.728del p.G243Afs*27 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- MS4A6A | c.355del p.V119Lfs*5 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- MTTP | c.856del p.A286Pfs*63 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- NPSR1 | c.280+1del | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- OR11H12 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by mutect2, varscan2
- OR5L2 | c.5del p.G2? | Frame Shift Del (DEL) | VAF 45/178 reads (25%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1422del p.A475Pfs*31 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel, varscan2
- PRPF40B | c.2359_2363del p.K787Efs*7 (on ENST00000380281; = p.K774Efs*7 on NM_012272.3) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- SERPINB7 | c.969del p.H323Qfs*5 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- SPATA31A1 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 78/358 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TPTE | c.1051G>T p.A351S (on ENST00000618007 / NM_199261.4; = p.A333S on NM_199259.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TRGJP2 | c.42G>T p.R14S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- TTYH1 | c.1054_1056del p.E352del | In Frame Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- UTP18 | c.1106C>A p.A369E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- ZNF292 | c.4827_4828del p.I1609Mfs*13 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- ZNF804A | c.590del p.N197Ifs*28 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- AFG3L2 | c.807C>T p.Y269= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52316241; called by muse, mutect2
- ALLC | c.1005T>C p.D335= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs753693577, COSV52996519; called by muse, mutect2, varscan2
- AMDHD2 | c.279C>T p.L93= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs150383216, COSV53551648; called by muse, mutect2, varscan2
- ANKH | c.147G>T p.L49= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV52483705; called by muse, mutect2
- ANKIB1 | c.2601T>C p.S867= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV56064089; called by muse, mutect2, varscan2
- BRIP1 | c.2754C>T p.T918= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs878855148, COSV52004451; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D1 | c.1950A>T p.P650= (on ENST00000356253 / NM_001366867.1; = p.P638= on NM_000722.4) | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as COSV62386115; called by muse, mutect2, varscan2
- CACNB2 | c.552G>T p.L184= (on ENST00000324631 / NM_201596.3; = p.L129= on NM_000724.4) | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV56637121; called by muse, mutect2, varscan2
- CALD1 | c.18T>A p.R6= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV62650924; called by muse, mutect2, varscan2
- CAMTA1 | c.489G>C p.R163= | Silent (SNP) | VAF 64/244 reads (26%) | catalogued as COSV57882875, COSV57915260; called by muse, mutect2, varscan2
- CC2D1A | c.1869G>A p.L623= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as rs941888866, COSV58784972; called by muse, mutect2
- CDR2 | c.558T>G p.G186= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV51675377, COSV51676921; called by muse, mutect2, varscan2
- CHRM1 | c.558C>A p.P186= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV61007267; called by muse, mutect2, varscan2
- CHRM4 | c.102C>T p.F34= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV63126958; called by muse, varscan2
- CNGB3 | c.1371C>A p.A457= | Silent (SNP) | VAF 38/239 reads (16%) | catalogued as COSV60687442; called by muse, mutect2, varscan2
- CNTLN | c.3891G>A p.V1297= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs751898496, COSV52088260; called by muse, mutect2, varscan2
- COL5A1 | c.1755G>T p.P585= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV65665075, COSV65672413; called by muse, mutect2, varscan2
- CSPP1 | c.2058C>G p.L686= (on ENST00000676605; = p.L645= on NM_024790.6) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV51588749; called by muse, mutect2, varscan2
- CTNNA2 | c.2745C>A p.P915= (on ENST00000402739 / NM_001282597.3; = p.P867= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV100559588; called by muse, mutect2, varscan2
- CYTH1 | c.600G>T p.L200= | Silent (SNP) | VAF 51/351 reads (15%) | catalogued as COSV63122246; called by muse, mutect2, varscan2
- DCT | c.375G>T p.V125= | Silent (SNP) | VAF 92/200 reads (46%) | catalogued as COSV65470173, COSV65470852; called by muse, mutect2, varscan2
- DHX36 | c.114A>T p.G38= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV57675140; called by muse, mutect2, varscan2
- DYM | c.171C>A p.T57= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV53988950; called by muse, mutect2, varscan2
- EPHA8 | c.591C>A p.L197= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1303340379, COSV51267541, COSV51279968, COSV51301272; called by muse, mutect2, varscan2
- FAT3 | c.1845C>T p.I615= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53082934; called by muse, mutect2, varscan2
- FCSK | c.3066T>C p.A1022= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV55373256; called by muse, mutect2, varscan2
- FLRT2 | c.1887C>G p.T629= | Silent (SNP) | VAF 71/331 reads (21%) | catalogued as COSV58146567; called by muse, mutect2, varscan2
- GBA3 | c.711G>T p.V237= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV72438441; called by muse, mutect2
- GET1-SH3BGR | c.684C>T p.A228= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV61323671; called by muse, mutect2, varscan2
- GLT6D1 | c.588C>A p.A196= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV65628120; called by muse, mutect2, varscan2
- GPC3 | c.726A>G p.T242= | Silent (SNP) | VAF 70/85 reads (82%) | catalogued as COSV63668401; called by muse, mutect2, varscan2
- GRIN1 | c.417C>A p.R139= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV59298912; called by muse, mutect2, varscan2
- GRIN2B | c.3456C>A p.T1152= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs752200554, COSV74206675, COSV74206895; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM5 | c.1570C>A p.R524= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV59616743; called by muse, mutect2, varscan2
- INAVA | c.1374C>T p.G458= | Silent (SNP) | VAF 140/245 reads (57%) | catalogued as rs752662505, COSV66257223; called by muse, mutect2, varscan2
- ITSN1 | c.519T>C p.A173= | Silent (SNP) | VAF 21/159 reads (13%) | catalogued as COSV66084535; called by muse, mutect2, varscan2
- JMJD6 | c.651C>T p.L217= | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as rs1429659753, COSV57974167, COSV57976186; called by muse, mutect2, varscan2
- JUN | c.438G>T p.A146= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100973387; called by muse, mutect2, varscan2
- KDM1A | c.1959G>A p.R653= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV56503540; called by muse, mutect2, varscan2
- KDR | c.2646C>A p.L882= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV55771296; called by muse, mutect2, varscan2
- LRFN2 | c.1500G>C p.T500= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV57831286; called by muse, mutect2, varscan2
- LRRC4C | c.372G>A p.A124= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs372663008; called by muse, mutect2
- LTB4R2 | c.1008G>T p.T336= (on ENST00000528054; = p.T305= on NM_019839.5) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV51866975; called by muse, mutect2, varscan2
- LUZP2 | c.387C>A p.L129= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100419139; called by muse, mutect2, varscan2
- MAGEB18 | c.84G>T p.T28= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV100305630, COSV57464623; called by muse, mutect2, varscan2
- MAGI1 | c.978A>G p.T326= | Silent (SNP) | VAF 44/68 reads (65%) | catalogued as rs147479917; called by muse, mutect2, varscan2
- MARCHF4 | c.825C>A p.I275= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV56106896; called by muse, mutect2, varscan2
- MBL2 | c.495C>A p.P165= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV64758997; called by muse, varscan2
- MCF2L | c.489C>T p.V163= (on ENST00000375608; = p.V131= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV65052237; called by muse, mutect2, varscan2
- MET | c.1278C>T p.R426= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs748508881, COSV59265380; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP26 | c.279G>A p.S93= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs149405690; called by muse, mutect2, varscan2
- MS4A14 | c.489G>T p.S163= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV55736618; called by muse, mutect2, varscan2
- MUC5B | c.5314T>C p.L1772= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs1255212287, COSV71594248; called by muse, mutect2, varscan2
- NEU2 | c.546G>T p.R182= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV52093448; called by muse, mutect2, varscan2
- NRXN3 | c.1635G>A p.V545= (on ENST00000335750 / NM_001330195.2; = p.V172= on NM_004796.6) | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV59779372; called by muse, mutect2, varscan2
- NTRK1 | c.1719G>T p.V573= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV62327273; called by muse, mutect2, varscan2
- NYAP2 | c.645T>C p.H215= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV56011593; called by muse, mutect2
- OR10G8 | c.570C>T p.D190= | Silent (SNP) | VAF 61/197 reads (31%) | catalogued as COSV70908991; called by muse, mutect2, varscan2
- OR5C1 | c.816G>A p.L272= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV65456483; called by muse, mutect2, varscan2
- OR5F1 | c.864G>T p.L288= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs757434417, COSV53549173, COSV53549271; called by mutect2, varscan2
- OXCT1 | c.312G>T p.R104= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99541811; called by muse, mutect2
- PCDHGA6 | c.180G>A p.A60= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53989788; called by muse, mutect2, varscan2
- PNMA3 | c.273G>T p.V91= | Silent (SNP) | VAF 41/55 reads (75%) | catalogued as COSV64722705; called by muse, mutect2, varscan2
- PRLHR | c.921C>A p.A307= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV53303885, COSV99492686; called by muse, mutect2, varscan2
- PTBP3 | c.1344T>G p.T448= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV57585184; called by muse, mutect2, varscan2
- PTPRZ1 | c.1842A>T p.P614= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV66441855; called by muse, mutect2, varscan2
- RNASE3 | c.285C>G p.L95= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV58959770; called by muse, mutect2, varscan2
- ROBO4 | c.756G>T p.P252= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV60626192; called by muse, mutect2, varscan2
- RP1L1 | c.4944C>A p.G1648= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV66757926, COSV66759120; called by muse, mutect2, varscan2
- SETBP1 | c.852G>T p.L284= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV56330051; called by muse, mutect2, varscan2
- SGSH | c.957G>T p.T319= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100413341; called by muse, mutect2, varscan2
- SLC13A1 | c.669C>A p.G223= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52014437; called by muse, mutect2, varscan2
- SLC39A12 | c.1668C>A p.G556= (on ENST00000377369 / NM_001145195.2; = p.G519= on NM_152725.3) | Silent (SNP) | VAF 56/96 reads (58%) | catalogued as COSV66200719; called by muse, mutect2, varscan2
- SLC5A5 | c.1818C>A p.P606= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV55832499; called by muse, mutect2, varscan2
- SLC6A17 | c.960C>A p.S320= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV58994982; called by muse, mutect2, varscan2
- SLC8B1 | c.1356G>T p.R452= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV52529498; called by muse, mutect2, varscan2
- SLITRK5 | c.1131G>T p.A377= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1261174372, COSV61524639; called by muse, mutect2, varscan2
- SORCS1 | c.2727G>A p.A909= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs747274447, COSV53887422; called by muse, mutect2, varscan2
- THTPA | c.279T>C p.C93= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV55339095; called by muse, mutect2
- TIGAR | c.561A>T p.P187= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV51628991; called by muse, mutect2, varscan2
- TLL1 | c.99T>C p.Y33= | Silent (SNP) | VAF 65/159 reads (41%) | catalogued as COSV50306573; called by muse, mutect2, varscan2
- TNFSF15 | c.415C>T p.L139= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV65010554; called by muse, mutect2, varscan2
- TRAV8-2 | c.195T>C p.L65= | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- UNC5D | c.984G>T p.R328= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99772841, COSV99774971; called by muse, mutect2, varscan2
- VN1R5 | c.820C>T p.L274= | Silent (SNP) | VAF 94/210 reads (45%) | catalogued as rs762570502; called by muse, mutect2, varscan2
- VPS41 | c.618G>T p.V206= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV56071331; called by muse, mutect2, varscan2
- WDR36 | c.105G>A p.L35= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as COSV72411354; called by muse, mutect2, varscan2
- ZFC3H1 | c.4641T>C p.N1547= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs1259584247, COSV66434538; called by muse, mutect2, varscan2
- ZNF423 | c.2833C>A p.R945= (on ENST00000563137 / NM_001379286.1; = p.R937= on NM_015069.4) | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV52193177, COSV52198294; called by muse, mutect2, varscan2
- ZNF512 | c.1308G>T p.V436= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV62677133; called by muse, mutect2, varscan2
- DCHS2 | n.660G>A | RNA (SNP) | VAF 7/33 reads (21%) | catalogued as rs536580730, COSV59724334, COSV99044894; called by muse, mutect2, varscan2
- GBA3 | c.59-8445G>T | Intron (SNP) | VAF 90/197 reads (46%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*367T>A | 3'UTR (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99336973; called by muse, mutect2, varscan2
- SSPOP | n.7787G>T | RNA (SNP) | VAF 5/50 reads (10%) | catalogued as COSV65133847; called by muse, mutect2, varscan2
- TRPM1 | c.724+1020A>T | Intron (SNP) | VAF 62/179 reads (35%) | catalogued as COSV56638508; called by muse, mutect2, varscan2
